ALCHEMIST case ALCH-B21A — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/9c7f9a6b-4706-4e74-89d9-01beb852fb35

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 66.8 years (24,389 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B21A-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B21A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B21A-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 48; Percent tumor nuclei: 65; Percent normal cells: 45; Percent necrosis: 0; Percent stromal cells: 7; Percent lymphocyte infiltration: 27; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
